HCMI case HCM-BROD-0926-C16 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/88808858-b4db-4ec6-a505-10339b498dcf

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1989; Vital status: Dead; Days to death: 372 days (1.0 years); Cause of death: Cancer Related.

Diagnoses (3)
1. Tubular adenocarcinoma (the primary disease): ICD-O-3 morphology code: 8211/3; ICD-10 code: C16.9; Tissue or organ of origin: Stomach, NOS; Classification of tumor: primary; Age at diagnosis: 30.9 years (11,285 days); AJCC staging edition: 8th; AJCC clinical stage: Stage IVB; AJCC pathologic T: TX; AJCC pathologic N: NX; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Tumor grade: G3; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Prior treatment: Yes; Sites of involvement: Ascites / Peritoneum, NOS.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Irinotecan + Leucovorin + Oxaliplatin; Treatment intent type: Neoadjuvant; Days to treatment start: 2 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 203 days; Days to treatment end: 231 days.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Ramucirumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 203 days; Days to treatment end: 231 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Docetaxel + Irinotecan; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 244 days; Days to treatment end: 301 days.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Pembrolizumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 302 days; Days to treatment end: 330 days; Treatment outcome: Treatment Ongoing.
   Recorded as not given: neoadjuvant Radiation Therapy, NOS; Surgery, NOS, for initial diagnosis.
2. Tubular adenocarcinoma: ICD-O-3 morphology code: 8211/6; ICD-10 code: C78.6; Tissue or organ of origin: Stomach, NOS; Site of resection or biopsy: Peritoneum, NOS; Classification of tumor: metastasis; Age at diagnosis: 30.9 years (11,285 days).
3. Tubular adenocarcinoma: ICD-O-3 morphology code: 8211/6; ICD-10 code: C78.6; Tissue or organ of origin: Stomach, NOS; Site of resection or biopsy: Peritoneum, NOS; Classification of tumor: metastasis; Age at diagnosis: 31.8 years (11,629 days); Days to diagnosis: 344 days.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Cisplatin + Docetaxel + Irinotecan + Leucovorin + Oxaliplatin + Pembrolizumab; Treatment intent type: Maintenance Therapy; Days to treatment start: 16 days; Days to treatment end: 330 days; Treatment outcome: Progressive Disease.

Follow-up (3 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Peritoneum, NOS; Days to progression: 0 days.
- Days to follow up: 366 days (1.0 years); Disease response: Progressive Disease; Progression or recurrence: Yes.
- Follow-up contact recording only the day: day 335.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 52 kg; Height: 167 cm; BMI: 18.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (3 samples)
- Sample HCM-BROD-0926-C16-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0926-C16-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
- Sample HCM-BROD-0926-C16-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen.
